Somatic mutation profile of tumor specimen C3L-00997-04 (aliquot CPT0123180009) from CPTAC case C3L-00997, project CPTAC-3 (Oropharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 47.2 years (17,253 days).
Specimen C3L-00997-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef9d2b22-2cd1-424b-9abb-23dae6e8629d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00997-31 (Blood Derived Normal), aliquot CPT0124760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28547711-d052-4004-8ab7-97d6e84ee729

The open-access MAF lists 164 somatic variants for this specimen: 111 protein-altering or splice-affecting, 27 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 27, Intron 12, RNA 7, Nonsense Mutation 6, In Frame Del 3, 5'Flank 2, 5'UTR 2, 3'Flank 2, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 120/339 reads (35%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC098582.1 | c.2282A>G p.Y761C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761433139; called by muse, mutect2
- AK9 | c.4429G>A p.A1477T | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.399); catalogued as rs1203404914; called by muse, mutect2, varscan2
- AXIN1 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51989653; called by muse, mutect2, varscan2
- BASP1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs1234911317; called by muse, mutect2
- BMPR1B | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 23/416 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV52778068; called by muse, mutect2
- CABLES2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs373923225, COSV99652968; called by muse, mutect2, varscan2
- CDH7 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.761); catalogued as COSV59887667; called by muse, mutect2, varscan2
- CHRDL2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs766056484, COSV55222562; called by muse, mutect2, varscan2
- COL27A1 | c.5339C>A p.T1780N | Missense Mutation (SNP) | VAF 189/579 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.139); catalogued as rs776273907; called by muse, mutect2, varscan2
- CPA1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377042960, CM139176; ClinVar: uncertain significance; called by muse, mutect2
- CTNNA3 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100373499; called by muse, mutect2, varscan2
- DMD | c.5321G>A p.G1774E | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV63776923; called by muse, mutect2, varscan2
- DSG2 | c.1097G>A p.S366N | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768504765; called by muse, mutect2, varscan2
- EDC4 | c.3662G>A p.R1221H | Missense Mutation (SNP) | VAF 81/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs986628771, COSV59304501; called by muse, mutect2, varscan2
- EIF3A | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 106/689 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs375001473; called by muse, varscan2
- ELK3 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778634088; called by muse, mutect2, varscan2
- EP300 | c.7102G>A p.D2368N | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV54343198; called by muse, mutect2, varscan2
- EYS | c.4009C>T p.H1337Y | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1204054236; called by muse, mutect2, varscan2
- IGF2R | c.303G>C p.L101F | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs1452078727; called by muse, mutect2
- KALRN | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV53759819; called by muse, mutect2, varscan2
- KMT5B | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 252/345 reads (73%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1479743038; called by muse, mutect2, varscan2
- LILRA1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 66/592 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs919874018, COSV52182057, COSV52185670; called by muse, mutect2, varscan2
- LMLN | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 64/339 reads (19%) | catalogued as rs770407626; called by muse, mutect2, varscan2
- MYO1E | c.2098C>T p.R700* | Nonsense Mutation (SNP) | VAF 95/249 reads (38%) | catalogued as rs1312503153; called by muse, mutect2, varscan2
- NCOR2 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100656984; called by muse, mutect2, varscan2
- NOTCH1 | c.2434G>T p.G812W | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53087407; called by muse, mutect2
- OR11L1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 251/619 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63313810, COSV63315822; called by muse, mutect2, varscan2
- OR13G1 | c.468C>A p.H156Q | Missense Mutation (SNP) | VAF 266/500 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as COSV62944508; called by muse, mutect2, varscan2
- OR1K1 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs372997295; called by muse, mutect2, varscan2
- OR6C2 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.665); catalogued as rs200382811, COSV59515609; called by muse, mutect2, varscan2
- PEG3 | c.3408C>A p.D1136E | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV55624431; called by muse, mutect2, varscan2
- PRDM10 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 59/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs896327755; called by muse, mutect2, varscan2
- PSMB2 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368316488, COSV100951597; called by muse, mutect2, varscan2
- PTGIS | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 152/553 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.523); catalogued as rs370701076; called by muse, mutect2, varscan2
- PYCR2 | c.445_456del p.L149_L152del | In Frame Del (DEL) | VAF 106/882 reads (12%) | catalogued as rs1396137555; called by mutect2, varscan2
- RELCH | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV56885392; called by muse, mutect2, varscan2
- SEMA5A | c.838C>A p.R280S | Missense Mutation (SNP) | VAF 124/520 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as COSV66786334; called by muse, mutect2, varscan2
- SH3BP5 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV53743894, COSV53745798; called by muse, mutect2, varscan2
- SLC11A1 | c.25A>T p.R9W | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as rs763570124; called by muse, mutect2, varscan2
- SLC6A11 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV54390034; called by muse, mutect2, varscan2
- SORCS1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1486573405, COSV53845136; called by muse, mutect2, varscan2
- ST6GAL1 | c.1040A>G p.K347R | Missense Mutation (SNP) | VAF 27/444 reads (6%) | PolyPhen benign (0.007); catalogued as rs774789937; called by muse, mutect2
- TBC1D20 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs750354297, COSV100830488; called by muse, mutect2, varscan2
- TGM1 | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 86/575 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs759302866; called by muse, mutect2, varscan2
- TMPO | c.922A>G p.I308V | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as rs1275960965; called by muse, mutect2, varscan2
- TPR | c.5986G>A p.D1996N | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs755986460; called by muse, mutect2, varscan2
- TSC2 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 42/781 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796053512, COSV54755895; ClinVar: uncertain significance / benign; called by muse, mutect2
- ZFAT | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 74/649 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs754938486; called by muse, mutect2, varscan2
- ZNF30 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV57854132; called by muse, mutect2, varscan2
- ZNF563 | c.917A>G p.E306G | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756353285; called by muse, mutect2, varscan2
- ADAM9 | c.329dup p.Q111Tfs*15 | Frame Shift Ins (INS) | VAF 26/142 reads (18%) | called by mutect2, pindel, varscan2
- ADAMTS8 | c.1367T>G p.F456C | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGBL1 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANKRD20A1 | c.1674G>C p.K558N | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ARHGAP33 | c.1444G>T p.G482* | Nonsense Mutation (SNP) | VAF 92/274 reads (34%) | called by muse, mutect2, varscan2
- ARMC8 | c.917A>C p.Y306S (on ENST00000469044 / NM_001363941.2; = p.Y292S on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/369 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC54 | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPAMD8 | c.5663C>A p.A1888D (on ENST00000651564; = p.A1841D on NM_015692.5) | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DECR1 | c.842C>G p.A281G | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- DHX9 | c.2164A>C p.I722L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMILIN2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ESPNL | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.115); called by muse, mutect2
- ETV2 | c.527C>A p.T176K | Missense Mutation (SNP) | VAF 77/465 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- F13A1 | c.1888A>G p.I630V | Missense Mutation (SNP) | VAF 73/504 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, varscan2
- FAM207A | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FGF13 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FMN2 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- GABPB2 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2
- GABRA2 | c.468T>A p.Y156* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- GABRG3 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GFI1 | c.924+1G>T p.X308_splice | Splice Site (SNP) | VAF 209/602 reads (35%) | called by muse, mutect2, varscan2
- GPR15 | c.808C>G p.R270G | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGA1 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- KCNA6 | c.934G>C p.G312R | Missense Mutation (SNP) | VAF 109/499 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KIAA1217 | c.5276G>T p.G1759V | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KMT2A | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRATD2 | c.625C>G p.R209G | Missense Mutation (SNP) | VAF 50/409 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LRP1B | c.2678G>C p.C893S | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP5 | c.2533C>A p.L845I | Missense Mutation (SNP) | VAF 60/979 reads (6%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.987); called by muse, mutect2
- LRRC24 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 100/442 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAPKAPK2 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD3L1 | c.386T>A p.V129E | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MGAT1 | c.102_113del p.G35_P38del | In Frame Del (DEL) | VAF 101/365 reads (28%) | called by mutect2, pindel, varscan2
- MGAT2 | c.969G>C p.L323F | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NDUFA11 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 91/617 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NIT2 | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PARD3 | c.3775T>A p.Y1259N | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEC | c.11302A>T p.I3768F (on ENST00000322810 / NM_201380.4; = p.I3658F on NM_000445.5) | Missense Mutation (SNP) | VAF 307/1423 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PSMA8 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PXDN | c.1325G>C p.R442T | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- RAI14 | c.1462A>G p.T488A | Missense Mutation (SNP) | VAF 74/295 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RC3H1 | c.2012A>G p.D671G | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RNF40 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 63/549 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- RSPRY1 | c.657A>G p.I219M | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- RUFY2 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RUNX2 | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 215/559 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SHISA3 | c.475T>C p.S159P | Missense Mutation (SNP) | VAF 25/476 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- SHOC1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A3 | c.881A>G p.E294G (on ENST00000228318 / NM_005888.3; = p.E293G on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/600 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2
- STX11 | c.862T>A p.*288Kext*41 | Nonstop Mutation (SNP) | VAF 24/420 reads (6%) | called by muse, mutect2
- TMEM53 | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMTC2 | c.2063C>A p.A688D | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TOMM70 | c.1230G>T p.L410= | Splice Region (SNP) | VAF 48/134 reads (36%) | called by muse, mutect2, varscan2
- YLPM1 | c.3177_3209del p.D1059_R1069del | In Frame Del (DEL) | VAF 23/238 reads (10%) | called by mutect2, pindel, varscan2
- ZAR1L | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 50/658 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2
- ZFP2 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF208 | c.1909T>C p.Y637H | Missense Mutation (SNP) | VAF 54/372 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); called by muse, varscan2
- ZNF521 | c.2762A>T p.K921M | Missense Mutation (SNP) | VAF 103/458 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ZNF679 | c.723A>C p.R241S | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- ZNF804A | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ALOX12B | c.552C>T p.F184= | Silent (SNP) | VAF 114/365 reads (31%) | called by muse, mutect2, varscan2
- ANKRD35 | c.642T>C p.A214= | Silent (SNP) | VAF 44/186 reads (24%) | called by muse, mutect2, varscan2
- C9 | c.24A>G p.A8= | Silent (SNP) | VAF 49/259 reads (19%) | called by muse, mutect2, varscan2
- CCDC74A | c.834C>T p.L278= | Silent (SNP) | VAF 32/540 reads (6%) | called by muse, mutect2
- CNTN2 | c.2541T>C p.Y847= | Silent (SNP) | VAF 50/265 reads (19%) | catalogued as rs1166209730; called by muse, mutect2, varscan2
- DLG5 | c.2634G>A p.Q878= | Silent (SNP) | VAF 74/271 reads (27%) | catalogued as rs770475131; called by muse, mutect2, varscan2
- DNAI2 | c.1674A>T p.A558= | Silent (SNP) | VAF 31/438 reads (7%) | called by muse, mutect2
- DUXA | c.333T>C p.S111= | Silent (SNP) | VAF 28/119 reads (24%) | called by muse, mutect2, varscan2
- ECT2 | c.1503T>A p.I501= (on ENST00000392692 / NM_001349098.2; = p.I470= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/313 reads (10%) | catalogued as rs763938525, COSV51690643; called by muse, mutect2
- ETV2 | c.528G>A p.T176= | Silent (SNP) | VAF 80/466 reads (17%) | called by muse, mutect2, varscan2
- GPR37 | c.1377C>T p.I459= | Silent (SNP) | VAF 38/175 reads (22%) | catalogued as COSV58255160, COSV58257355; called by muse, mutect2, varscan2
- HLA-G | c.384G>A p.G128= | Silent (SNP) | VAF 49/287 reads (17%) | called by muse, mutect2, varscan2
- IL17RA | c.2265C>A p.L755= | Silent (SNP) | VAF 149/1071 reads (14%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.1038G>A p.R346= | Silent (SNP) | VAF 34/311 reads (11%) | called by muse, mutect2, varscan2
- KRT25 | c.756G>A p.L252= | Silent (SNP) | VAF 32/265 reads (12%) | catalogued as COSV100379857; called by muse, mutect2, varscan2
- PCDHGA4 | c.2067C>T p.V689= | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as rs1207950942; called by muse, mutect2
- PKD1L1 | c.7383C>A p.A2461= | Silent (SNP) | VAF 34/313 reads (11%) | called by muse, mutect2, varscan2
- SFMBT2 | c.1309C>T p.L437= | Silent (SNP) | VAF 47/176 reads (27%) | catalogued as COSV62808699; called by muse, mutect2, varscan2
- SLC12A8 | c.1374C>T p.F458= | Silent (SNP) | VAF 31/468 reads (7%) | catalogued as COSV58871089; called by muse, mutect2
- TDP1 | c.822C>T p.G274= | Silent (SNP) | VAF 91/732 reads (12%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.291T>G p.P97= | Silent (SNP) | VAF 49/420 reads (12%) | called by muse, mutect2, varscan2
- UNC5B | c.2052C>A p.G684= | Silent (SNP) | VAF 93/566 reads (16%) | catalogued as rs774215015, COSV58982594; called by muse, mutect2, varscan2
- VAX2 | c.744C>G p.V248= | Silent (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- ZEB1 | c.2763A>G p.R921= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as rs762799225; called by muse, mutect2, varscan2
- ZFP28 | c.1701A>G p.R567= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- ZNF419 | c.801C>T p.S267= | Silent (SNP) | VAF 41/261 reads (16%) | catalogued as rs1328617801; called by muse, mutect2, varscan2
- ZNF700 | c.1482G>A p.R494= | Silent (SNP) | VAF 100/430 reads (23%) | called by muse, mutect2, varscan2
- AC099548.2 | n.241C>G | RNA (SNP) | VAF 21/122 reads (17%) | called by mutect2, varscan2
- ANXA8L1 | chr10:46375770 G>A | 5'Flank (SNP) | VAF 53/690 reads (8%) | called by muse, mutect2
- CLIC2 | c.58-10451G>T | Intron (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- DCHS2 | n.838T>G | RNA (SNP) | VAF 24/100 reads (24%) | catalogued as rs775366790; called by muse, mutect2, varscan2
- DDAH1 | c.304-45550G>C | Intron (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
- EP400P1 | n.368C>T | RNA (SNP) | VAF 30/219 reads (14%) | called by muse, mutect2, varscan2
- FAM157B | n.485G>A | RNA (SNP) | VAF 8/595 reads (1%) | catalogued as rs1172488217; called by muse, mutect2
- FLOT2 | c.132-1595G>A | Intron (SNP) | VAF 18/428 reads (4%) | called by muse, mutect2
- GVINP1 | n.4356A>T | RNA (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2
- GVINP1 | n.4354T>A | RNA (SNP) | VAF 22/212 reads (10%) | called by muse, mutect2
- IKBIP | c.297+7713A>T | Intron (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- LRRC63 | chr13:46270565 A>G | 3'Flank (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- MARCHF8 | c.242+1078G>T | Intron (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2
- MIR6511B2 | chr16:15130776 T>C | 3'Flank (SNP) | VAF 116/477 reads (24%) | called by muse, mutect2, varscan2
- NFS1 | c.409-1710C>G | Intron (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- PARK7 | c.322+12G>T | Intron (SNP) | VAF 98/630 reads (16%) | called by muse, mutect2, varscan2
- PYCR3 | c.-10A>T | 5'UTR (SNP) | VAF 26/240 reads (11%) | called by muse, mutect2, varscan2
- RPE | c.564+617C>T | Intron (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- SEMA5A | c.*35A>C | 3'UTR (SNP) | VAF 50/290 reads (17%) | called by muse, mutect2, varscan2
- SLC17A8 | c.-4C>G | 5'UTR (SNP) | VAF 15/439 reads (3%) | called by muse, mutect2
- SNX32 | c.785+10C>A | Intron (SNP) | VAF 25/193 reads (13%) | called by muse, mutect2, varscan2
- SSUH2 | n.489A>T | RNA (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- TAPT1 | chr4:16226962 C>T | 5'Flank (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- TIMM8B | c.84+377C>T | Intron (SNP) | VAF 31/190 reads (16%) | called by muse, mutect2, varscan2
- TMEM59L | c.664+16G>T | Intron (SNP) | VAF 20/636 reads (3%) | called by muse, mutect2
- ZNF252P | n.245+4601del | Intron (DEL) | VAF 76/452 reads (17%) | called by mutect2, pindel, varscan2
